Surgical pathology report (de-identified scan), TCGA case TCGA-ZH-A8Y3, project TCGA-CHOL (Cholangiocarcinoma), tissue source site University of North Carolina, specimen TCGA-ZH-A8Y3-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Liver, anterior segment 2-3 edge, biopsy

- No carcinoma identified
- Intraoperative diagnosis confirmed

B: Liver, posterior segment, 2-3 edge, biopsy

- Positive for adenocarcinoma
- Intraoperative diagnosis confirmed

*ICD-O-3
Cholangiocarcinoma 8160/3
Site: Intrahepatic bile duct
022.1*

C: Liver, right, partial hepatectomy

QD 4/13/14

Tumor histologic type: Adenocarcinoma, consistent with intrahepatic cholangiocarcinoma (see comment)

Histologic grade: Well to moderately differentiated (grade 1-2 of 4)

Tumor growth pattern (per AJCC staging manual, 7th ed.): Mass forming growth pattern

Tumor size and extent: 6.2 cm in largest dimension (gross measurement)

Focality: Unifocal

Tumor location: Right hepatic lobe

Vascular invasion: Present, tumor invades into portal vein branches and into vena cava (see also specimen D)

Perineural invasion: Identified in specimen D

Invasion of liver capsule: Present; tumor invades into but not through the liver capsule

Necrosis: No significant tumor necrosis present; tumor is 90% viable, with prominent desmoplastic stroma

Margins:

- Parenchymal resection margins: Positive for carcinoma
- Vascular resection margins: Negative for carcinoma

[page 2 of 4]
- Bile duct margin: Indefinite for dysplasia, favor reactive epithelial changes; negative for invasive carcinoma

Background liver parenchyma: Cholestasis and moderate periportal inflammation; mild portal fibrous expansion; no cirrhosis present

- Although some fibrosis surrounding larger bile ducts in the vicinity of the tumor is present, it is not the concentric (onion-skin type) fibrosis typically seen in primary sclerosing cholangitis (PSC). The findings are not diagnostic for PSC. Correlation with clinical and radiographic findings is recommended.

Gallbladder: Unremarkable gallbladder without calculi; negative for malignancy

Lymph nodes: One pericystic lymph node, negative for metastatic carcinoma (0/1)

AJCC stage (7th edition): pT2a pN0

D: Liver, caval margin, resection

- Positive for adenocarcinoma
- Perineural invasion present

Comment:

Immunohistochemical stains were performed on block C4 with the following results:

Cytokeratin 7: Strongly positive in adenocarcinoma

Cytokeratin 20: Negative in adenocarcinoma

CDX2: Negative in adenocarcinoma

Estrogen receptor: Negative in adenocarcinoma

GCDFP-15: Negative in adenocarcinoma

TTF-1: Negative in adenocarcinoma

Interpretation: While the staining pattern is not entirely specific, it is compatible with an intrahepatic cholangiocarcinoma in the appropriate clinical setting (if other primary sites have been excluded).

The case has been discussed at

on

[page 3 of 4]
Intraoperative Consult Diagnosis:

A frozen section was requested by Dr. in OR

FSA1: Liver, anterior segment, 2-3 edge, biopsy

- No evidence of malignancy

FSB1: Liver, posterior segment, 2-3 edge, biopsy

- Invasive adenocarcinoma

Drs. on at

Frozen Section Pathologist:

Clinical History:

-year-old female with recent diagnosis of large central liver mass with associated biliary and right portal vein occlusion with associated periportal/upper abdominal adenopathy; outside pathology shows rare atypical glands suspicious for malignancy.

Gross Description:

Received are four formalin-filled containers.

Container A: Received fresh for frozen section and additionally labeled "anterior segment 2-3 edge" is a 3.2 x 1.6 x 0.5 cm fragment of red/tan soft tissue that is frozen section entirely as FSA1,

Container B: Received fresh for frozen section and additionally labeled "posterior segment 2-3 edge" is a 2.2 x 1.0 x 0.5 cm fragment of red/tan soft tissue that is frozen entirely as FSB1,

Container C:

Specimen Type: right lobectomy

Specimen Weight: 630 grams

Measurement: 17 x 15 x 6 cm

Mass: A 5.3 x 5.0 x 3.8 cm white circumscribed, firm, fleshy mass with peripheral extension to nearby ducts and surrounding the ducts. Adjacent to the mass is a 1.5 x 0.7 x 0.5 cm area of yellow soft discoloration. The total size including this yellow area is 6.2 x 5.5 x 4.1 cm. The mass grossly abuts the capsule and the blue inked parenchymal margin. On the capsule there is an area of white discoloration that is inked black. This area is adjacent to the mass. The tumor appears to invade into portal vein branches.

[page 4 of 4]
Adjacent liver tissue: green/brown mottled and congested

Capsule: The capsule is normal, purple/tan, smooth and glistening.

Comment: The parenchymal resection margin is inked blue.

Major portal vein/ hepatic vein: There is no gross evidence of vascular invasion.

Gallbladder: 9.9 x 2.7 x 1.1 cm. The serosa is purple/red, smooth and glistening. The wall averages 0.4 cm thick and is lined by a red velvety mucosa with diffuse yellow stippling. The gallbladder contains a small amount of red thin bile. Stones are grossly absent. One cystic duct lymph node is identified measuring 1.4 x 0.7 x 0.4 cm.

Block summary:

C1 - hilar vascular margins and cystic duct

C2 - parenchymal stapled vascular margins

C3-C5 - mass with respect to blue inked parenchymal margin and capsule

C6 - mass with extension

C7 - mass surrounding bile duct

C8 - mass surrounding bile duct

C9 - mass surrounding bile duct

C10 - mass with adjacent uninvolved

C11 - possible area of necrosis

C12 - uninvolved

C13 - gallbladder and cystic duct lymph node

Container D is additionally labeled "margin caval." It holds a 3.6 x 2.1 x 1 cm fragment of red/tan soft tissue that is inked, serially sectioned and submitted entirely in blocks D1-D4,

Source: NCI Genomic Data Commons file 90f9a502-fa33-473a-a2c5-f81ffb5ad893 (TCGA-ZH-A8Y3.C4E66BC9-DCF0-43A6-B6B8-24D8FC02A7DB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).